ALCHEMIST case ALCH-B1YA — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/8b0434aa-6fcb-40b2-8957-7d95f639ed2c

Demographics
Sex at birth: male.

Diagnoses (1)
1. Adenosquamous carcinoma: Age at diagnosis: 75.3 years (27,489 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B1YA-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B1YA-TTP1-C: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B1YA-TTP1-C-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 30; Percent normal cells: 2; Percent necrosis: 0; Percent stromal cells: 58; Percent lymphocyte infiltration: 100; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 100.
